Somatic mutation profile of tumor specimen TARGET-30-PARDYU-01A (aliquot TARGET-30-PARDYU-01A-01D) from TARGET case TARGET-30-PARDYU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 5.3 years (1,942 days).
Specimen TARGET-30-PARDYU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58d29ed3-c5bd-4650-85d5-905db5a783b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARDYU-10A (Blood Derived Normal), aliquot TARGET-30-PARDYU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24852008-5f88-4e8d-8600-e4252234327f

The open-access MAF lists 18 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 14, Nonsense Mutation 1, Frame Shift Del 1, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD247 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV62978519; called by muse, mutect2, varscan2
- ERICH1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs765504989, COSV50637126; called by muse, mutect2, varscan2
- FCAR | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 103/224 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV62029913; called by muse, mutect2, varscan2
- HSPG2 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 58/64 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV65930332, COSV65930398; called by muse, mutect2, varscan2
- KDM5A | c.5025C>A p.F1675L | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV66993035; called by muse, mutect2, varscan2
- LY9 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV54434746; called by muse, mutect2, varscan2
- PRB1 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 141/409 reads (34%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.041); catalogued as COSV53704135; called by muse, mutect2, varscan2
- PREX2 | c.3533G>T p.G1178V | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55775786, COSV55786310, COSV99905418; called by muse, mutect2, varscan2
- RPL7L1 | c.403del p.Q135Rfs*3 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | catalogued as rs1188486343; called by pindel, varscan2
- SEC14L5 | c.1688G>T p.R563L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV52039030, COSV52041120; called by muse, mutect2, varscan2
- SHANK2 | c.3179C>A p.P1060Q | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV53601586; called by muse, mutect2, varscan2
- SIGLEC1 | c.3586G>A p.D1196N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52465382; called by muse, mutect2
- TMEM63A | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as rs990276807, COSV64763224; called by muse, mutect2, varscan2
- WWP1 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs910319561, COSV55360057; called by muse, mutect2, varscan2
- ZNF483 | c.1662C>A p.S554R | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV58515923; called by muse, mutect2, varscan2
- ZNF486 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782634381, COSV58719581; called by muse, mutect2, varscan2
- SNRPD1 | c.297_308del p.R112_G115del | In Frame Del (DEL) | VAF 32/85 reads (38%) | called by mutect2, varscan2
- ABHD2 | c.939C>A p.G313= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV61774487; called by muse, mutect2, varscan2
